Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8591, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8591-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]		

[page 2 of 4]
Diagnosis Details	Comments

[page 3 of 4]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Antrum
Tumor size: 10 x 9 x 1 cm
Tumor features: Ulcerated, Annular
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Adjacent structures
(specify) - Lesser omentum
Lymph nodes: 14/14 positive for
metastasis (Intraabdominal 14/14)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not
specified
Additional pathologic findings: Not
specified
Comments: None

ID

[page 4 of 4]
Excision date

Source: NCI Genomic Data Commons file 5a2b4e62-21a7-4331-b932-8710b3563173 (TCGA-BR-8591.EAC8321E-E75D-426D-8DB2-A7E89AE3E8A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).